MMRF case MMRF_1210 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2dcda5a0-4cd2-4162-9bea-cc5f1433724b

Demographics
Sex at birth: male; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.2 years (24,550 days); ISS stage: I; Days to last known disease status: 1,643 days (4.5 years); Days to last follow up: 1,643 days (4.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 156 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 246 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,324 days (3.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,503 days (4.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 8 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 15.6 g/L; Beta 2 Microglobulin 3.29 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 10.3 g/dL; Glucose 5.28 mmol/L.
- Day 89 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 10.5 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 396 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 192 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 9.05 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.78 mmol/L.
- Day 237 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 4.25 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.04 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 140 µmol/L; Total Protein 6 g/dL.
- Day 370 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 4.98 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.32 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 447 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.43 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.04 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 503 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 6.87 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.36 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.78 mmol/L.
- Day 636 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 6.65 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.22 mmol/L.
- Day 701: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 8.05 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.33 mmol/L.
- Day 867 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 9.01 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.23 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 979 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 10.3 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 1,055 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 6.01 g/L; Hemoglobin 8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.77 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 6 mmol/L.
- Day 1,126 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 6.48 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.01 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.02 mmol/L; Albumin 38 g/L; Total Protein 5 g/dL; Glucose 7.54 mmol/L.
- Day 1,215: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 7.35 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.01 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Glucose 7.48 mmol/L.
- Day 1,388 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 11.3 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.53 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 8.31 mmol/L.
- Day 1,465 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 11.2 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L.
- Day 1,643 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 5.03 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 8: Weight: 112 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_1210_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 8 days.
- Sample MMRF_1210_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 8 days.
- Sample MMRF_1210_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,388 days (3.8 years).
